CCDI case PBCDAI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/a5c4ceea-9dc0-465a-99b4-fce38a066137

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Hepatocellular carcinoma, fibrolamellar: ICD-O-3 morphology code: 8171/3; Tissue or organ of origin: Liver; Age at diagnosis: 14.8 years (5,392 days).

Biospecimens (3 samples)
- Sample 0DP6HI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP6HW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DP6I8: Tissue type: Tumor; Specimen type: Solid Tissue.
